TARGET case TARGET-30-PADSEC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9db13a94-1c77-5470-b16a-5ffb8b666a39

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 665 days (1.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 4.0 years (1,476 days); Year of diagnosis: 1994; Days to last follow up: 665 days (1.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Treatment given: Protocol identifier: 3891.
   Treatment given: Protocol identifier: B003.
   Treatment given: Protocol identifier: B954.

Follow-up (2 entries)
- Days to follow up: 428 days (1.2 years); Days to first event: 428 days (1.2 years); First event: Event.
- Days to follow up: 665 days (1.8 years); Year of follow up: 1996.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PADSEC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PADSEC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 665
- Protocol: 3891, B003, B954
- Histology: Unfavorable
- ICDO Description: Abdominal adrenal right side retroperitoneal--no intraspinal ext. Size: 25cm x 18cm x 12.5cm Mets: LN, BM, bone
